Surgical pathology report (de-identified scan), TCGA case TCGA-64-5774, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Fox Chase, specimen TCGA-64-5774-01A (Primary Tumor).

[page 1 of 2]
Clinical History/Diagnosis: Right lung cancer.

Source of Specimen(s):

A: Portion of sixth Rib

B: Mediastinal Lymph Node Level 9

C: Right Level 4 L.N.

D: Level 7 L.N.

E: Right Lung

TCGA-64-5774

Gross Description:

Received in five parts.

Source of Tissue: 1. Labeled #1 "portion of sixth rib"

Gross Description: Received fresh is a 1.5 cm in greatest dimension tan fragment of rib having a minimal amount of attached soft tissue. A representative section is submitted in one block, following decalcification.

Designation of Sections: block 1

Summary of Sections: undesignated - 1

Source of Tissue: 2. Labeled #2 "mediastinal lymph node level 9"

Gross Description: Received fresh are two gray-black anthracotic stained lymph nodes, 0.8 cm in greatest dimension. They are submitted in toto in one block.

Designation of Sections: block 2

Summary of Sections: undesignated - 2

Source of Tissue: 3. Labeled #3 "right level 4 lymph node"

Gross Description: Received fresh are two gray-black anthracotic stained tissue fragments, 1.0 cm in greatest dimension. They are entirely submitted in one block.

Designation of Sections: block 3

Summary of Sections: undesignated - multiple

Source of Tissue: 4. Labeled #4 "level 7 lymph node"

Gross Description: Received fresh are 3.0 x 2.0 x 0.8 cm of yellow-tan fibroadipose tissue. The fragments are sectioned to reveal multiple anthracotic stained lymph nodes, 1.5 cm in greatest dimension. The tissue is entirely submitted in four blocks.

[page 2 of 2]
Designation of Sections: 4A-4D

CGA-64-5774

Summary of Sections: multiple

Source of Tissue: 5. Labeled #5 "right lung"

Frozen Section Diagnosis: 5FS NEGATIVE MARGIN OF RESECTION PER

Gross Description: Received fresh for frozen section evaluation is a 797 gm, 20.0 x 20.0 x 5.5 cm right pneumonectomy. It is covered by a pink-red to purple focally anthracotic stained pleura having up to 2.0 cm of attached bronchus. The bronchial resection margin is submitted for frozen section evaluation and the frozen section residue is submitted in one block. In the hilar area, adjacent to the bronchus is a 7.0 x 5.0 x 3.0 cm firm mass having tan anthracotic stained cut surfaces. The remaining cut surfaces of lung range from areas which are tan-pink and crepitant to areas which are red-purple, soft and glistening. There are multiple palpable hilar lymph nodes, 1.0 cm in greatest dimension. The cut surface of each is gray-black and anthracotic stained. Representative sections are submitted in eleven blocks.

Designation of Sections: 5FS frozen section bronchial resection margin, 5A vascular margins, 5B-5F tumor, 5G-5H random lung sections, 5I-5K hilar lymph nodes

Summary of Sections: multiple

Final Diagnosis:

1. Portion of 6th rib, excision:
- No tumor seen.
2. Mediastinal lymph node, level 9, excision:
- No tumor seen in four lymph nodes (0/4).
3. Right level 4 lymph node s, excision:
- No tumor seen in five lymph nodes (0/5).
4. Level 7 lymph nodes, excision:
- No tumor seen in thirteen lymph nodes (0/13).
5. Right lung, pneumonectomy:
- Poorly differentiated adenocarcinoma with clear cell changes (7 cm); no invasion of visceral pleura.
- Negative bronchial and vascular margins.
- No tumor seen in fifteen peribronchial lymph nodes (0/15).

Source: NCI Genomic Data Commons file 9502e800-2f50-4057-9a1c-d657e3862f9b (TCGA-64-5774.D8D1FECD-1290-4D5A-A98B-3C29F789BDE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).